Somatic mutation profile of tumor specimen TCGA-X6-A7WD-01A (aliquot TCGA-X6-A7WD-01A-21D-A351-09) from TCGA case TCGA-X6-A7WD, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 63.9 years (23,341 days).
Specimen TCGA-X6-A7WD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5decb780-4880-4b8f-b9d7-9542e8f077e0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-X6-A7WD-10A (Blood Derived Normal), aliquot TCGA-X6-A7WD-10A-01D-A351-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/afda1243-003d-4f7a-936d-2bfb2a78ac4f

The open-access MAF lists 44 somatic variants for this specimen: 31 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 29, Silent 13, In Frame Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.1654C>T p.R552* | Nonsense Mutation (SNP) | VAF 25/36 reads (69%) | hotspot (GDC flag); catalogued as rs121913303, CM961229, COSV57297124; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCB4 | c.1475A>G p.Y492C | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV99710733; called by muse, mutect2, varscan2
- ATP13A4 | c.1854C>A p.D618E | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.43); PolyPhen benign (0.021); catalogued as COSV99794775; called by muse, mutect2, varscan2
- ATP2A2 | c.1101C>A p.F367L | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.025); catalogued as COSV100428732; called by muse, mutect2, varscan2
- CACNA1H | c.6685A>T p.R2229W | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV99326851; called by muse, varscan2
- CBLIF | c.934A>G p.I312V | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.593); catalogued as COSV99951005; called by muse, mutect2, varscan2
- CD209 | c.532G>T p.A178S | Missense Mutation (SNP) | VAF 67/177 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.364); catalogued as COSV99214133; called by muse, mutect2, varscan2
- CHD7 | c.1270G>T p.V424F | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.651); catalogued as CD060584, COSV101418317; called by muse, mutect2, varscan2
- CHRNA5 | c.188G>A p.R63H | Missense Mutation (SNP) | VAF 59/139 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs202057419, COSV55137286, COSV55140132; called by muse, mutect2, varscan2
- COL11A2 | c.4613G>A p.G1538E (on ENST00000341947 / NM_080680.3; = p.G1431E on NM_080679.2) | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV100554239; called by muse, mutect2, varscan2
- COL6A3 | c.7481T>C p.V2494A | Missense Mutation (SNP) | VAF 29/40 reads (73%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); catalogued as COSV99799418; called by muse, mutect2, varscan2
- DIAPH2 | c.2320C>A p.L774I | Missense Mutation (SNP) | VAF 23/33 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100233599; called by muse, mutect2, varscan2
- GABRR1 | c.724C>T p.R242W | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs200602822; called by muse, mutect2, varscan2
- GFI1B | c.347G>T p.G116V | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT tolerated (0.47); PolyPhen benign (0.015); catalogued as COSV100254306; called by muse, mutect2, varscan2
- GRIA4 | c.142A>G p.I48V | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT tolerated (0.76); PolyPhen benign (0.035); catalogued as rs766289231, COSV56921197; called by muse, mutect2, varscan2
- KDM4A | c.869A>G p.N290S | Missense Mutation (SNP) | VAF 24/28 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100969544; called by muse, mutect2, varscan2
- NPTX2 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs747205631, COSV99674987; called by muse, mutect2, varscan2
- OR10Q1 | c.45G>T p.E15D | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.501); catalogued as COSV100372336; called by muse, mutect2, varscan2
- PENK | c.793A>G p.M265V | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV100152389; called by muse, mutect2, varscan2
- PHKB | c.190C>G p.Q64E | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54516145; called by muse, varscan2
- POLE | c.4411C>T p.R1471C | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs528264567, COSV57693254; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLN | c.2516A>C p.Q839P | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.653); catalogued as COSV100526825; called by muse, mutect2, varscan2
- PRAG1 | c.431G>C p.G144A | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT tolerated (0.54); PolyPhen benign (0.012); catalogued as COSV100422415; called by muse, mutect2, varscan2
- SAMD9L | c.458A>G p.K153R | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100560873; called by muse, mutect2
- SSH1 | c.2590G>A p.A864T | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.007); catalogued as rs776283064, COSV99044328; called by muse, mutect2, varscan2
- TBX5 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs374906778, CM155953; called by muse, mutect2, varscan2
- TSPYL6 | c.128G>T p.R43L | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.055); catalogued as rs537805712, COSV100336710, COSV57820000; called by muse, mutect2, varscan2
- UBE2G2 | c.314G>A p.S105N | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT tolerated (0.38); PolyPhen benign (0.226); catalogued as COSV100446131; called by muse, mutect2, varscan2
- ZNF385B | c.641C>A p.P214H | Missense Mutation (SNP) | VAF 19/159 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.357); catalogued as COSV100416141, COSV61177946; called by muse, mutect2, varscan2
- GNPTAB | c.1367_1369del p.C456_N457delinsY | In Frame Del (DEL) | VAF 26/80 reads (33%) | called by pindel, varscan2
- MROH1 | c.4100G>C p.S1367T | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CARMIL3 | c.912C>T p.L304= | Silent (SNP) | VAF 29/67 reads (43%) | catalogued as COSV100549699; called by muse, mutect2, varscan2
- CHEK2 | c.1338G>C p.G446= (on ENST00000382580 / NM_001005735.2; = p.G403= on NM_007194.4) | Silent (SNP) | VAF 28/80 reads (35%) | catalogued as COSV100101969; called by muse, mutect2, varscan2
- COQ5 | c.706C>T p.L236= | Silent (SNP) | VAF 20/44 reads (45%) | catalogued as COSV99942376; called by muse, mutect2, varscan2
- KCNJ12 | c.964C>T p.L322= | Silent (SNP) | VAF 10/236 reads (4%) | catalogued as COSV100054537, COSV59165564, COSV59167745; called by muse, mutect2
- LPCAT1 | c.1479G>A p.P493= | Silent (SNP) | VAF 14/89 reads (16%) | catalogued as rs1231161601, COSV99359116; called by muse, mutect2, varscan2
- NEB | c.4330T>C p.L1444= | Silent (SNP) | VAF 19/147 reads (13%) | catalogued as COSV99424857; called by muse, mutect2, varscan2
- NEBL | c.1248G>A p.L416= | Silent (SNP) | VAF 14/17 reads (82%) | catalogued as COSV65803286; called by muse, mutect2, varscan2
- OR9G4 | c.390G>A p.L130= | Silent (SNP) | VAF 23/64 reads (36%) | catalogued as COSV100265178; called by muse, mutect2, varscan2
- PLEKHO1 | c.1065G>T p.T355= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as rs372807467, COSV99215294; called by muse, mutect2, varscan2
- SYNPO | c.1782G>A p.K594= (on ENST00000394243 / NM_001166208.2; = p.K350= on NM_007286.6) | Silent (SNP) | VAF 21/56 reads (38%) | catalogued as COSV100302250; called by muse, mutect2, varscan2
- SYT8 | c.234G>A p.R78= | Silent (SNP) | VAF 23/60 reads (38%) | catalogued as rs540038185, COSV99425521; called by muse, mutect2, varscan2
- TG | c.4635C>T p.D1545= | Silent (SNP) | VAF 13/85 reads (15%) | catalogued as rs751370448, COSV55073574; called by muse, mutect2, varscan2
- ZNF570 | c.922C>A p.R308= | Silent (SNP) | VAF 36/86 reads (42%) | catalogued as COSV100356236, COSV57578220; called by muse, mutect2, varscan2
